TCGA case TCGA-AD-6899 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Colon; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ea923671-3903-4a79-830d-e7e4b1eabab0

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 84 years; Vital status: Dead; Days to death: 176 days.

Diagnoses (1)
1. Mucinous adenocarcinoma: ICD-O-3 morphology code: 8480/3; ICD-10 code: C18.9; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Cecum; Classification of tumor: primary; Age at diagnosis: 84.0 years (30,693 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T4a; AJCC pathologic N: N2b; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 176 days.
   Pathology details: Circumferential resection margin: 1; Consistent pathology review: Yes; Lymph nodes positive: 17; Lymph nodes tested: 20; Lymphatic invasion present: Yes; Non nodal tumor deposits: No; Vascular invasion present: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 48 days; Disease response: Tumor Free.
- Days to follow up: 176 days; Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 6.1 ng/mL.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 62 kg; Height: 175 cm; BMI: 20.2.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AD-6899-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 1; Shortest dimension: 0.4.
  Slide TCGA-AD-6899-01A-01-BS1: Section location: Bottom; Percent tumor cells: 67; Percent tumor nuclei: 55; Percent normal cells: 0; Percent necrosis: 8; Percent stromal cells: 25.
  Slide TCGA-AD-6899-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 25; Percent lymphocyte infiltration: 20.
- Sample TCGA-AD-6899-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AD-6899-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Colon Mucinous Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Cecum; Lymph nodes examined: Yes; CEA level pretreatment: 6.1; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 176 days; disease-specific survival: no event (censored), 176 days; disease-free interval: no event (censored), 176 days; progression-free interval: no event (censored), 176 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AD-6899-01A-11D-1923-01): tumor purity 0.62, ploidy 2.47, whole-genome doublings 1.
